Gene-level copy-number profile of tumor specimen TCGA-33-4538-01A from TCGA case TCGA-33-4538, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.2 years (24,174 days).
Specimen TCGA-33-4538-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.96264899-1571-4376-b400-2494206a9988.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-33-4538-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/97867cba-6d9c-4bcb-bb9f-9ab94e5c08a7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 113; copy number 2: 21,536; copy number 3: 18,055; copy number 4: 16,390; copy number 5: 2,437; copy number 6: 814; copy number 7: 58; copy number 8: 28; copy number 9: 3; copy number 10: 24; copy number 12: 74; copy number 13: 268; copy number 15: 2; copy number 24: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-33-4538-01A-01D-1195-01): tumor purity 0.59, ploidy 3.06, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,715 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:94,725,674–142,131,016, 905 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr2:142,131,178–181,680,665, 547 genes, copy number 5–9 (within-gene range 2–9) (broad region; genes not listed).
- chr2:186,354,570–206,621,127, 334 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr3:143,855,739–180,542,836, 520 genes, copy number 5–24 (broad region; genes not listed).
- chr3:180,983,709–183,910,936, 60 genes, copy number 13: DNAJC19, SOX2-OT, AC083904.1, RNU6-4P, FAUP2, AC068308.1, RPL7AP25, AC125613.1, AC125613.2, AC117415.1, SOX2, AC117415.2, RN7SL703P, RNA5SP150, AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.2, AC012081.1, AC109131.1, AC084211.1, LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1, MCCC1, MCCC1-AS1, LAMP3, MCF2L2, B3GNT5, RNA5SP151, LINC00888, SNORA63D, AC092960.2, SNORA63E, AC092960.1, AC092960.3, KLHL6, KLHL6-AS1, AC068769.1, KLHL24, YEATS2, YEATS2-AS1, AC131160.1, MAP6D1, PARL, RPSAP31, MIR4448, CYP2AB1P.
- chr3:184,095,118–186,772,986, 74 genes, copy number 12 (within-gene range 4–12) (broad region; genes not listed).
- chr10:111,498,191–111,498,941, 1 gene, copy number 5: RPS6P15.
- chr11:38,618,264–40,112,599, 8 genes, copy number 8–24: LINC02759, LINC01493, AC021723.2, AC021723.1, RNU6-99P, AC021749.1, AC021820.1, AC080100.1.
- chr11:40,351,564–40,351,672, 1 gene, copy number 8: Y_RNA.
- chr14:35,819,224–36,679,362, 26 genes, copy number 8–15: AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1, ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, AL079303.1, PAX9.
- chr17:26,981,694–30,108,452, 167 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr17:30,709,299–30,790,908, 1 gene, copy number 5 (within-gene range 4–5): SUZ12P1.
- chr17:30,769,388–32,997,877, 102 genes, copy number 5 (broad region; genes not listed).
- chr17:33,052,107–33,131,743, 3 genes, copy number 5: AC003687.1, AC008133.2, AC008133.1.
- chr18:69,659,837–69,724,975, 2 genes, copy number 6: AC068254.2, AC068254.1.
- chr19:27,638,483–38,332,076, 362 genes, copy number 6–10 (broad region; genes not listed).
- chr22:25,327,252–32,498,829, 255 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr22:35,400,134–40,682,814, 206 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr22:42,500,568–49,052,549, 141 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 113. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
